Somatic mutation profile of tumor specimen TCGA-D3-A5GS-06A (aliquot TCGA-D3-A5GS-06A-11D-A27K-08) from TCGA case TCGA-D3-A5GS, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 58.6 years (21,393 days).
Specimen TCGA-D3-A5GS-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c54d7fb-5533-4f3b-8d27-f43462391f2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A5GS-10A (Blood Derived Normal), aliquot TCGA-D3-A5GS-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc855ef5-c084-4e42-b562-2f9f64e1e13d

The open-access MAF lists 490 somatic variants for this specimen: 310 protein-altering or splice-affecting, 166 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 274, Silent 166, Nonsense Mutation 18, Intron 7, Splice Site 6, Splice Region 5, Frame Shift Del 5, RNA 4, 3'UTR 2, In Frame Del 1, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PCSK5 | c.2772G>A p.W924* | Nonsense Mutation (SNP) | VAF 23/74 reads (31%) | hotspot (GDC flag); catalogued as rs1170804599, COSV70449546; called by muse, mutect2, varscan2
- ABCA8 | c.2254G>A p.G752R | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV52201215; called by muse, mutect2, varscan2
- ABCC6 | c.1786G>A p.V596M | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1413781077, COSV52743857; called by muse, mutect2
- ACAP1 | c.309C>G p.H103Q | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV50135966; called by muse, mutect2, varscan2
- ACSM4 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68067721; called by muse, mutect2, varscan2
- ACVRL1 | c.1218G>A p.W406* | Nonsense Mutation (SNP) | VAF 26/56 reads (46%) | catalogued as CM050028, COSV66360195; called by muse, mutect2, varscan2
- ADAMTS2 | c.1684G>A p.G562S | Missense Mutation (SNP) | VAF 93/295 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757782312, COSV52363513; called by muse, mutect2, varscan2
- ADAP2 | c.657G>A p.K219= | Splice Region (SNP) | VAF 9/37 reads (24%) | catalogued as rs755413282, COSV58295938; called by muse, mutect2, varscan2
- ADCY1 | c.1134G>A p.M378I | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV52034631; called by muse, mutect2, varscan2
- ADGRB3 | c.2639C>T p.T880I | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV53244712; called by muse, mutect2, varscan2
- ADGRB3 | c.4135G>A p.E1379K | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as COSV53244726; called by muse, mutect2, varscan2
- AKT1 | c.932G>A p.G311D | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62573416; called by muse, mutect2, varscan2
- ALDH3A2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.091); catalogued as rs1226690400, COSV51566756; called by muse, mutect2, varscan2
- ALPK3 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV51933315; called by muse, mutect2, varscan2
- ANAPC4 | c.1725-1G>A p.X575_splice | Splice Site (SNP) | VAF 5/12 reads (42%) | catalogued as COSV59544122; called by muse, mutect2, varscan2
- ANGPT1 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 74/131 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); catalogued as COSV52440135; called by muse, mutect2, varscan2
- ANKRD28 | c.1372G>A p.V458M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs763041699, COSV67518066; called by mutect2, varscan2
- ANKRD30A | c.1455G>A p.R485= (on ENST00000611781; = p.R429= on NM_052997.2) | Splice Region (SNP) | VAF 16/60 reads (27%) | catalogued as COSV64610191; called by muse, varscan2
- ANKRD44 | c.2013-2A>G p.X671_splice | Splice Site (SNP) | VAF 30/74 reads (41%) | catalogued as COSV56555153, COSV56562203; called by muse, mutect2, varscan2
- APOB | c.5398G>A p.D1800N | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.159); catalogued as COSV51935259; called by muse, mutect2, varscan2
- ARFGEF3 | c.3283C>T p.R1095W | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.857); catalogued as rs952834056, COSV52457413; called by muse, mutect2, varscan2
- ARHGAP29 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 39/51 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53110295, COSV99558207; called by muse, mutect2, varscan2
- ARHGAP36 | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs1026063857, COSV52266761; called by muse, mutect2, varscan2
- ARHGEF5 | c.4537C>T p.P1513S | Missense Mutation (SNP) | VAF 73/325 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.136); catalogued as rs1320497038, COSV50210336; called by muse, mutect2, varscan2
- ARMC4 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV53462458; called by muse, mutect2, varscan2
- ASCC3 | c.5149C>T p.L1717F | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100976913, COSV64975116; called by muse, mutect2, varscan2
- ASTN1 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs760442147, COSV56061330; called by muse, mutect2, varscan2
- BCAM | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as COSV54302264; called by muse, mutect2, varscan2
- BEST3 | c.1900G>A p.A634T | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as COSV58301509; called by muse, mutect2, varscan2
- BTBD16 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV53263068; called by muse, mutect2, varscan2
- C20orf85 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as COSV64519331; called by muse, mutect2, varscan2
- C20orf85 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100959338, COSV64519981; called by muse, mutect2, varscan2
- C3 | c.4486G>A p.E1496K | Missense Mutation (SNP) | VAF 65/140 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as rs1217543591, COSV55572948; called by muse, mutect2, varscan2
- C3 | c.3475G>A p.E1159K | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as rs367654112, COSV99836011; called by muse, mutect2, varscan2
- C4orf17 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 36/81 reads (44%) | catalogued as COSV58512410; called by muse, mutect2, varscan2
- C6 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs267600638, COSV54704649; called by muse, mutect2, varscan2
- C7 | c.1756G>A p.G586S | Missense Mutation (SNP) | VAF 46/77 reads (60%) | SIFT tolerated (0.58); PolyPhen benign (0.045); catalogued as COSV57474394; called by muse, mutect2, varscan2
- C8B | c.534G>A p.G178= | Splice Region (SNP) | VAF 98/136 reads (72%) | catalogued as COSV64777626; called by muse, mutect2, varscan2
- CACNA1A | c.970C>T p.L324F | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV64198041, COSV64210813; called by muse, mutect2, varscan2
- CACNA1E | c.3982G>A p.E1328K | Missense Mutation (SNP) | VAF 81/189 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV62387196; called by muse, mutect2, varscan2
- CACNA2D3 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55535127, COSV55537315; called by muse, mutect2, varscan2
- CAPZA3 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs769365098, COSV56850079; called by muse, mutect2, varscan2
- CCDC136 | c.1555C>T p.L519F | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1165071082, COSV52799518; called by muse, mutect2, varscan2
- CCDC158 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as COSV66355108, COSV66355593; called by muse, mutect2, varscan2
- CD1E | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63771001; called by muse, mutect2, varscan2
- CD1E | c.1087C>T p.Q363* | Nonsense Mutation (SNP) | VAF 44/117 reads (38%) | catalogued as COSV63771007; called by muse, mutect2, varscan2
- CD248 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1340355370, COSV60936459; called by muse, mutect2, varscan2
- CD6 | c.1822C>A p.Q608K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV57838532; called by muse, mutect2
- CDC45 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54245412; called by muse, mutect2, varscan2
- CDH6 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs865858310, COSV54069887; called by muse, mutect2, varscan2
- CDKN2A | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 35/39 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs137854598, CM1414338, COSV58689032, COSV58690567; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CELSR1 | c.5854C>T p.P1952S | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.573); catalogued as COSV53085229; called by muse, mutect2, varscan2
- CFAP221 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV54657382; called by muse, mutect2, varscan2
- CFH | c.3319G>A p.G1107R | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.191); catalogued as COSV66408499; called by muse, mutect2, varscan2
- CFHR2 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs867746464, COSV66380395; called by muse, mutect2, varscan2
- CFTR | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs906983070, COSV50048120; called by muse, mutect2, varscan2
- CHGB | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV66760475; called by muse, mutect2, varscan2
- CMYA5 | c.9488G>A p.G3163E | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs769260361, COSV71405900; called by muse, mutect2, varscan2
- COL21A1 | c.2861G>A p.G954E | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55158848; called by muse, mutect2, varscan2
- COL3A1 | c.2647C>T p.P883S | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV58587878; called by muse, mutect2, varscan2
- COL5A2 | c.3703G>A p.D1235N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.666); catalogued as rs1185247065, COSV66409780; called by muse, mutect2, varscan2
- COPA | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54101536; called by muse, mutect2, varscan2
- CPNE5 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV55196508; called by muse, mutect2, varscan2
- CSMD1 | c.3818C>T p.S1273L (on ENST00000520002; = p.S1272L on NM_033225.6) | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.28); PolyPhen benign (0.265); catalogued as rs371526159, COSV100146309, COSV59323979; called by muse, mutect2, varscan2
- CTNNA3 | c.2225G>A p.G742E | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV101041160; called by muse, mutect2, varscan2
- CTNNA3 | c.2224G>A p.G742R | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV101041161; called by muse, mutect2, varscan2
- CUBN | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV64701471; called by muse, mutect2, varscan2
- CUL4A | c.1105A>C p.K369Q (on ENST00000375440 / NM_001008895.4; = p.K269Q on NM_003589.3) | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV58372915; called by muse, mutect2, varscan2
- CXCR2 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1298311873, COSV59279763; called by muse, mutect2, varscan2
- DACH1 | c.1720G>A p.E574K (on ENST00000619232 / NM_001366712.1; = p.E522K on NM_080759.6) | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV57498706, COSV57499795; called by muse, mutect2, varscan2
- DBX1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs1000434461, COSV57054047; called by muse, mutect2, varscan2
- DDX60L | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52713570; called by muse, mutect2, varscan2
- DEFB121 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 68/131 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs746005479, COSV66236307; called by muse, mutect2, varscan2
- DISP1 | c.2870C>T p.S957L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.227); catalogued as rs191290309, COSV52658137; called by muse, mutect2, varscan2
- DKK2 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53393923; called by muse, mutect2, varscan2
- DLEC1 | c.873+1G>A p.X291_splice | Splice Site (SNP) | VAF 14/42 reads (33%) | catalogued as COSV57299712; called by muse, mutect2, varscan2
- DLGAP2 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 75/114 reads (66%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.998); catalogued as rs1404079466, COSV70098229; called by muse, mutect2, varscan2
- DMGDH | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV54863595; called by muse, mutect2, varscan2
- DNAH5 | c.3544G>A p.E1182K | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs868077328, COSV54224694; called by muse, mutect2, varscan2
- DNAH7 | c.8327C>T p.P2776L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1282994095, COSV56764989; called by muse, mutect2, varscan2
- DNAH7 | c.3305G>A p.G1102E | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56752065; called by muse, mutect2, varscan2
- DNAH8 | c.10140-1G>A p.X3380_splice | Splice Site (SNP) | VAF 28/70 reads (40%) | catalogued as COSV59445015; called by muse, mutect2, varscan2
- DNAH9 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.168); catalogued as rs201765760; called by muse, mutect2, varscan2
- DNAI2 | c.715G>A p.G239R | Missense Mutation (SNP) | VAF 111/371 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100209631, COSV56758707; called by muse, mutect2, varscan2
- DPYSL5 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as COSV99981560; called by muse, mutect2, varscan2
- DSTYK | c.1108C>T p.L370F | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65686508; called by muse, mutect2, varscan2
- DTL | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65342366; called by muse, mutect2, varscan2
- E2F8 | c.1730C>T p.T577I | Missense Mutation (SNP) | VAF 96/172 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV51463460; called by muse, mutect2, varscan2
- EFNB1 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52661692; called by muse, mutect2, varscan2
- EHMT1 | c.2237C>T p.A746V | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.557); catalogued as COSV100603417; called by muse, mutect2, varscan2
- EPHA3 | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV60695883; called by muse, mutect2, varscan2
- EPPK1 | c.2936C>T p.P979L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV73261264; called by muse, mutect2, varscan2
- ERAP2 | c.1714C>T p.Q572* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV65938755, COSV65939682; called by muse, mutect2, varscan2
- EYA2 | c.847C>T p.H283Y | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs866808798, COSV57943122; called by muse, mutect2, varscan2
- EZR | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV61453816; called by muse, mutect2, varscan2
- F5 | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 66/209 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV63123857; called by muse, mutect2, varscan2
- FAM166B | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.025); catalogued as COSV63428575; called by muse, mutect2, varscan2
- FAM222A | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.582); catalogued as COSV62723330; called by muse, mutect2, varscan2
- FAM71B | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.018); catalogued as rs1207459118, COSV100261675; called by muse, mutect2, varscan2
- FAT4 | c.10561G>A p.E3521K | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58685307; called by muse, mutect2, varscan2
- FCGR2A | c.220C>T p.Q74* (on ENST00000271450 / NM_001136219.3; = p.Q73* on NM_021642.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 43/128 reads (34%) | catalogued as rs867685604, COSV54838749; called by muse, mutect2, varscan2
- FLG | c.1658G>A p.G553E | Missense Mutation (SNP) | VAF 353/712 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as COSV64241808; called by muse, mutect2, varscan2
- FLNC | c.4583C>T p.P1528L | Missense Mutation (SNP) | VAF 153/756 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57955841; called by muse, mutect2, varscan2
- FREM1 | c.4660C>A p.Q1554K | Missense Mutation (SNP) | VAF 47/70 reads (67%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV66523588; called by muse, mutect2, varscan2
- FSTL5 | c.2108G>A p.G703D | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100051479; called by muse, mutect2, varscan2
- FSTL5 | c.2107G>A p.G703S | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); catalogued as COSV100051482; called by muse, mutect2, varscan2
- FUT9 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.755); catalogued as rs146406553, COSV56142363; called by muse, mutect2, varscan2
- GCKR | c.1651G>A p.D551N | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV53107925; called by muse, mutect2, varscan2
- GCNT3 | c.1280A>T p.Y427F | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as COSV68532192; called by muse, mutect2, varscan2
- GDF1 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs1438404071; called by muse, mutect2
- GLT1D1 | c.664G>C p.A222P (on ENST00000442111 / NM_001366889.1; = p.A142P on NM_144669.3) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV55882058; called by muse, mutect2, varscan2
- GNAT2 | c.275G>C p.G92A | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV63554932; called by muse, mutect2, varscan2
- GOT2 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 67/83 reads (81%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.75); catalogued as COSV55331637; called by muse, mutect2, varscan2
- GPRC5C | c.467C>T p.P156L (on ENST00000652232; = p.P111L on NM_018653.4) | Missense Mutation (SNP) | VAF 125/195 reads (64%) | SIFT tolerated (0.27); PolyPhen benign (0.051); catalogued as COSV61236898; called by muse, mutect2, varscan2
- GRAMD1C | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.188); catalogued as COSV63982753; called by muse, mutect2, varscan2
- GRIN2A | c.2169-1G>A p.X723_splice | Splice Site (SNP) | VAF 16/41 reads (39%) | catalogued as COSV58032849; called by muse, mutect2, varscan2
- GRIN3A | c.1839G>A p.W613* | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as COSV62453726; called by muse, mutect2
- GRIN3A | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.117); catalogued as rs746403087, COSV62453733; called by muse, mutect2, varscan2
- HEATR6 | c.1976C>T p.S659F | Missense Mutation (SNP) | VAF 51/232 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV51745807; called by muse, mutect2, varscan2
- HGF | c.1943G>A p.G648E | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55949545; called by muse, mutect2, varscan2
- HHATL | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV60041798; called by muse, mutect2, varscan2
- HIVEP2 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV50012878; called by muse, mutect2, varscan2
- HNF1A | c.462G>A p.M154I | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV57462239; called by muse, mutect2, varscan2
- HOMER2 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58486126; called by muse, mutect2, varscan2
- HSD3B1 | c.53G>A p.R18K | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as COSV52490654; called by muse, mutect2, varscan2
- IGFL3 | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58242768; called by muse, mutect2, varscan2
- IGHV4-34 | c.186G>A p.W62* | Nonsense Mutation (SNP) | VAF 44/121 reads (36%) | catalogued as rs11546807; called by muse, mutect2, varscan2
- IGKC | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1263982487; called by muse, mutect2, varscan2
- IGSF5 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs780927418; called by muse, mutect2
- IL1R1 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52106138; called by muse, mutect2, varscan2
- IL36A | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs866220179, COSV52082919; called by muse, mutect2, varscan2
- IL4I1 | c.253-2A>G p.X85_splice | Splice Site (SNP) | VAF 16/40 reads (40%) | catalogued as COSV62009946; called by muse, mutect2, varscan2
- IMPG1 | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs866504491, COSV100886646, COSV64057738; called by muse, mutect2
- ITGA9 | c.197G>A p.G66D | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99291196; called by muse, mutect2, varscan2
- JAKMIP1 | c.1768C>T p.Q590* | Nonsense Mutation (SNP) | VAF 48/155 reads (31%) | catalogued as COSV51530505; called by muse, mutect2, varscan2
- JCAD | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV64759620; called by muse, mutect2, varscan2
- KCNH5 | c.2029C>T p.R677C | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750874924, COSV59752526; called by muse, mutect2, varscan2
- KCNH8 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs1248326207, COSV60463831; called by muse, mutect2, varscan2
- KIAA1210 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs750103202, COSV68177207; called by muse, mutect2, varscan2
- KIAA1217 | c.1814G>A p.R605K | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56816646; called by muse, mutect2, varscan2
- KIAA1614 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62550871; called by muse, mutect2, varscan2
- KIR3DL1 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58490661; called by muse, mutect2, varscan2
- KLHL4 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 37/38 reads (97%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); catalogued as COSV64140940, COSV64150226; called by muse, mutect2, varscan2
- KLK2 | c.87G>A p.W29* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as COSV100319873, COSV57569203; called by muse, mutect2, varscan2
- KPNA3 | c.1137G>A p.K379= | Splice Region (SNP) | VAF 16/51 reads (31%) | catalogued as COSV55504758, COSV99903873; called by muse, mutect2, varscan2
- KRT27 | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.526); catalogued as COSV56970742, COSV56971798; called by muse, mutect2, varscan2
- KRTAP10-5 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 71/120 reads (59%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs1362677994, COSV59962201; called by muse, mutect2, varscan2
- LAMA1 | c.5506G>A p.D1836N | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV67536950; called by muse, mutect2, varscan2
- LAMA1 | c.3112G>A p.E1038K | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0.045); catalogued as rs780567585, COSV67534714; called by muse, mutect2, varscan2
- LARGE1 | c.1625C>T p.P542L | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61661865; called by muse, mutect2, varscan2
- LCE1F | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.658); catalogued as COSV57669275; called by muse, mutect2, varscan2
- LMTK2 | c.1906T>G p.F636V | Missense Mutation (SNP) | VAF 73/130 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV51995714; called by muse, mutect2, varscan2
- LOXL2 | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs780665877, COSV66691463; called by muse, mutect2, varscan2
- LRIT2 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs540658121, COSV60561597; called by muse, mutect2, varscan2
- LRP2 | c.11566C>T p.P3856S | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.186); catalogued as COSV55543862; called by muse, mutect2, varscan2
- LRRN1 | c.287A>G p.N96S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751390851, COSV60013895; called by muse, mutect2, varscan2
- LRRTM4 | c.1225C>T p.Q409* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as COSV69140127; called by muse, mutect2, varscan2
- LUZP2 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267602831, COSV61199276; called by muse, mutect2, varscan2
- MAGEC1 | c.2063C>T p.S688F | Missense Mutation (SNP) | VAF 55/74 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); catalogued as COSV53570847; called by muse, mutect2, varscan2
- MAGEC2 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 97/120 reads (81%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs775326703, COSV55998560, COSV55999152; called by muse, mutect2, varscan2
- MCHR2 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.877); catalogued as COSV56002939; called by muse, mutect2, varscan2
- MICB | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as rs1199443184, COSV52856526; called by muse, mutect2, varscan2
- MPP7 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.51); catalogued as rs767641039, COSV61731060; called by muse, mutect2, varscan2
- MRPL11 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60599003; called by muse, mutect2, varscan2
- MTUS2 | c.2245C>T p.P749S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as rs939999445, COSV70916758; called by muse, mutect2, varscan2
- MUC16 | c.3683C>T p.S1228L | Missense Mutation (SNP) | VAF 132/313 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as rs778561167, COSV67465815; called by muse, mutect2, varscan2
- MUC16 | c.2602G>A p.E868K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs763691043, COSV67448892; called by muse, mutect2, varscan2
- MUCL1 | c.60G>A p.Q20= | Splice Region (SNP) | VAF 11/30 reads (37%) | catalogued as COSV58192538, COSV58193855; called by muse, mutect2, varscan2
- MYH1 | c.3481A>T p.T1161S | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.483); catalogued as COSV56848425; called by muse, mutect2, varscan2
- MYH3 | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); catalogued as COSV56864942; called by muse, mutect2, varscan2
- MYH6 | c.5102G>A p.R1701Q | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762103586, COSV62452468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH8 | c.3130G>A p.E1044K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV67965058; called by muse, mutect2, varscan2
- MYO6 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.264); catalogued as COSV64119005; called by muse, mutect2, varscan2
- NCOA5 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 82/192 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV51644347; called by muse, mutect2, varscan2
- NDST4 | c.2337G>A p.M779I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV52119880; called by muse, mutect2, varscan2
- NELL1 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54265365; called by muse, mutect2, varscan2
- NFATC3 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 86/109 reads (79%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV60473649; called by muse, mutect2, varscan2
- NLRP2 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54755085; called by muse, mutect2, varscan2
- NLRP9 | c.1243C>T p.L415F | Missense Mutation (SNP) | VAF 70/140 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.752); catalogued as COSV60463052; called by muse, mutect2, varscan2
- NMUR1 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs763080675, COSV59404247; called by muse, mutect2, varscan2
- NPAP1 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.097); catalogued as COSV61503881; called by muse, mutect2, varscan2
- NPAS1 | c.1516G>A p.D506N | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as COSV53409300; called by muse, mutect2, varscan2
- NPHS1 | c.2641C>T p.P881S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.207); catalogued as COSV62287622; called by muse, mutect2, varscan2
- NPPB | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV64687567; called by muse, mutect2, varscan2
- NPY2R | c.1048C>T p.H350Y | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV61527326; called by muse, mutect2, varscan2
- NPY5R | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as rs866941603, COSV58451682; called by muse, mutect2, varscan2
- NR1D1 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.206); catalogued as COSV52842995; called by muse, mutect2, varscan2
- NRXN1 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58452634; called by muse, mutect2
- NRXN3 | c.3214A>T p.T1072S (on ENST00000335750 / NM_001330195.2; = p.T699S on NM_004796.6) | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.979); catalogued as COSV59749171; called by muse, mutect2, varscan2
- NT5C1B | c.631G>A p.E211K (on ENST00000359846 / NM_001199086.2; = p.E151K on NM_033253.4) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.02); catalogued as rs767189136, COSV58395945; called by muse, mutect2, varscan2
- NT5E | c.511G>C p.V171L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as COSV57628370; called by muse, mutect2, varscan2
- NUGGC | c.668G>A p.R223K | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58434737; called by muse, mutect2, varscan2
- NXF1 | c.1571A>T p.N524I | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.303); catalogued as COSV53672125, COSV53674086; called by muse, mutect2, varscan2
- OMG | c.624C>A p.D208E | Missense Mutation (SNP) | VAF 78/214 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV55988019; called by muse, mutect2, varscan2
- OR10G7 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1456940965, COSV57867089; called by muse, mutect2, varscan2
- OR10G9 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100901439; called by muse, mutect2, varscan2
- OR10K2 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV59221193; called by muse, mutect2, varscan2
- OR2T12 | c.866G>A p.S289N | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV58777466; called by muse, mutect2, varscan2
- OR4E2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 201/242 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs866396121, COSV57731749; called by muse, mutect2, varscan2
- OR51T1 | c.187T>C p.Y63H | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59025448; called by muse, mutect2, varscan2
- OR52N5 | c.868T>C p.Y290H | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV57698871; called by muse, mutect2, varscan2
- OR5K3 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 87/230 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV67349994; called by muse, mutect2, varscan2
- OR5L2 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 46/73 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs1409482641, COSV65724065; called by muse, mutect2, varscan2
- OR6K6 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs779056999, COSV63744109; called by muse, mutect2, varscan2
- OSBPL7 | c.1711C>T p.R571* | Nonsense Mutation (SNP) | VAF 27/103 reads (26%) | catalogued as rs1299320469, COSV50108788; called by muse, mutect2, varscan2
- PADI2 | c.1897G>A p.D633N | Missense Mutation (SNP) | VAF 56/91 reads (62%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.954); catalogued as rs148845742; called by muse, mutect2, varscan2
- PAK5 | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 50/150 reads (33%) | catalogued as COSV62027416; called by muse, mutect2, varscan2
- PASK | c.3131C>T p.P1044L | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV99298404; called by muse, mutect2, varscan2
- PCBP4 | c.1025C>T p.P342L (on ENST00000322099 / NM_033010.2; = p.P299L on NM_020418.4) | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.505); catalogued as COSV59054645; called by muse, mutect2, varscan2
- PCDHGA1 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.097); catalogued as rs999390317, COSV65296460; called by muse, mutect2, varscan2
- PCED1B | c.1249C>T p.R417* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV71395206; called by muse, mutect2, varscan2
- PCLO | c.11623G>A p.E3875K | Missense Mutation (SNP) | VAF 200/682 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV61635209; called by muse, mutect2, varscan2
- PDE6B | c.2080A>T p.S694C | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV55326451; called by muse, mutect2, varscan2
- PDP1 | c.908G>A p.G303D | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV52601571; called by muse, mutect2, varscan2
- PHF21B | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57558324; called by muse, mutect2, varscan2
- PLEC | c.13166C>T p.S4389F (on ENST00000322810 / NM_201380.4; = p.S4279F on NM_000445.5) | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs782259278, COSV59635899; called by muse, mutect2, varscan2
- PLG | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV51982219; called by muse, mutect2, varscan2
- PLXDC2 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV65916249; called by muse, mutect2, varscan2
- PPP2R3C | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV54832814, COSV99808522; called by muse, mutect2, varscan2
- PRIMA1 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.469); catalogued as COSV60263739; called by muse, mutect2, varscan2
- PRKCG | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 77/199 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV54727721; called by muse, mutect2, varscan2
- PRLR | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1197065260, COSV51495677; called by muse, mutect2, varscan2
- PRMT8 | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV54214138; called by muse, mutect2, varscan2
- PRPF3 | c.148C>T p.H50Y | Missense Mutation (SNP) | VAF 110/263 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV61394795; called by muse, mutect2, varscan2
- PTH1R | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs772490281, COSV57315608, COSV57317957; called by muse, mutect2, varscan2
- PTPN11 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV61009048; called by muse, mutect2, varscan2
- PTPRK | c.2045C>T p.P682L | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as rs1176884785, COSV100950971, COSV63897884; called by muse, mutect2, varscan2
- PXDNL | c.2773C>T p.P925S | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs1390297647, COSV62487318; called by muse, mutect2, varscan2
- RAB3A | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 96/220 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs961892301, COSV55852284; called by muse, mutect2, varscan2
- RAPGEF5 | c.686A>G p.N229S (on ENST00000401957 / NM_001367602.2; = p.N532S on NM_012294.5) | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV59782986; called by muse, mutect2, varscan2
- RBM12 | c.1973C>T p.P658L | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV58291494; called by muse, mutect2, varscan2
- RCOR3 | c.1301C>T p.P434L | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV65365652; called by muse, mutect2, varscan2
- RELN | c.5899G>A p.E1967K | Missense Mutation (SNP) | VAF 52/81 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as COSV58987963, COSV59002199; called by muse, mutect2, varscan2
- REV3L | c.1954G>A p.V652I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV62618953; called by muse, mutect2, varscan2
- RFPL1 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.071); catalogued as COSV62977895; called by muse, mutect2, varscan2
- RGS22 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 81/146 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs1250563210, COSV62661667; called by muse, mutect2, varscan2
- ROBO1 | c.3598G>A p.E1200K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs77618957, COSV101458225; called by muse, mutect2, varscan2
- RPH3A | c.719G>A p.R240Q (on ENST00000389385 / NM_001143854.2; = p.R236Q on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.978); catalogued as rs772596187, COSV66991104; called by muse, mutect2, varscan2
- RPTOR | c.3153G>A p.W1051* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV60808387; called by muse, mutect2, varscan2
- RUFY4 | c.1078G>A p.G360R | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.621); catalogued as COSV60247548; called by muse, mutect2, varscan2
- RUNX1T1 | c.1075C>T p.H359Y (on ENST00000265814 / NM_001198628.1; = p.H332Y on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV56146901; called by muse, mutect2, varscan2
- RYR1 | c.9248C>T p.S3083L | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV62097235; called by muse, mutect2, varscan2
- SAMD9L | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 92/142 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as rs763348860, COSV59081544, COSV59081667; called by muse, mutect2, varscan2
- SBSPON | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866466373, COSV52076547; called by muse, mutect2, varscan2
- SCGB1C1 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV57293799; called by mutect2, varscan2
- SCN1A | c.1216G>A p.V406I | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as CM100964, COSV57669986; called by muse, mutect2, varscan2
- SCN5A | c.2165C>T p.T722I | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV61124092; called by muse, mutect2, varscan2
- SCN9A | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1323727395, COSV57609872; called by muse, mutect2, varscan2
- SEMA4C | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs749593966, COSV59690859; called by muse, mutect2, varscan2
- SIPA1L1 | c.1662C>A p.D554E | Missense Mutation (SNP) | VAF 79/249 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV62170207, COSV62173343; called by muse, mutect2, varscan2
- SLAMF8 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.037); catalogued as COSV56988412; called by muse, mutect2, varscan2
- SLC26A5 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs763236243, COSV59703899; called by muse, mutect2, varscan2
- SLC5A1 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 134/306 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767673239, COSV56684905; called by muse, mutect2, varscan2
- SLCO1A2 | c.1829G>A p.G610E | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs1266211052, COSV56602029; called by muse, mutect2, varscan2
- SLIT2 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as rs201524539, COSV56572517; called by muse, mutect2, varscan2
- SLITRK4 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 44/49 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62023896; called by muse, mutect2, varscan2
- SMARCAD1 | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.601); catalogued as COSV62774421; called by muse, mutect2, varscan2
- SNX15 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV57246938; called by muse, mutect2, varscan2
- SORCS3 | c.3149C>T p.P1050L | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1013405023, COSV63810505, COSV63816062; called by muse, mutect2, varscan2
- SPAG17 | c.3229G>A p.D1077N | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.683); catalogued as COSV60458805; called by muse, mutect2, varscan2
- SPARCL1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 98/264 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV56803035, COSV56803226; called by muse, mutect2, varscan2
- SPATA17 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV65119512; called by muse, mutect2, varscan2
- ST18 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV52494262; called by muse, mutect2, varscan2
- ST7L | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1210696267, COSV58308982; called by muse, mutect2, varscan2
- STAC | c.61G>A p.G21S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV56210729; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3223G>A p.E1075K | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as COSV59130555, COSV59132309; called by muse, mutect2, varscan2
- SUPT6H | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 26/68 reads (38%) | catalogued as COSV58927339; called by muse, mutect2, varscan2
- TAS2R41 | c.908G>A p.G303D | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs773957962, COSV68765242; called by muse, mutect2
- TAS2R60 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.159); catalogued as rs267601365, COSV60330294, COSV60330850; called by muse, mutect2, varscan2
- TAT | c.974G>A p.G325E | Missense Mutation (SNP) | VAF 53/63 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100587426; called by muse, mutect2, varscan2
- TAT | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 52/62 reads (84%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV100587427; called by muse, mutect2, varscan2
- TCN2 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV53191392; called by muse, mutect2, varscan2
- TEX13A | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100780596, COSV61166911; called by muse, mutect2, varscan2
- THBS1 | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV52952052; called by muse, mutect2, varscan2
- TJP1 | c.3314C>T p.P1105L | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.031); catalogued as COSV62041955; called by muse, mutect2, varscan2
- TMC5 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV101196741, COSV66866106; called by muse, mutect2, varscan2
- TMPRSS11F | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.113); catalogued as rs377605520; called by muse, mutect2, varscan2
- TRIM73 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100099673; called by mutect2, varscan2
- TRIM75P | c.465G>C p.L155F | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as rs1436729033; called by muse, mutect2, varscan2
- TTN | c.74528C>T p.P24843L (on ENST00000591111; = p.P17419L on NM_003319.4) | Missense Mutation (SNP) | VAF 81/228 reads (36%) | PolyPhen probably damaging (0.999); catalogued as COSV100629710, COSV60060986; called by muse, mutect2, varscan2
- TTN | c.66680G>A p.R22227Q (on ENST00000591111; = p.R14803Q on NM_003319.4) | Missense Mutation (SNP) | VAF 83/188 reads (44%) | PolyPhen benign (0.396); catalogued as rs763316990, COSV60061049; called by muse, mutect2, varscan2
- TTN | c.58232C>T p.P19411L (on ENST00000591111; = p.P11987L on NM_003319.4) | Missense Mutation (SNP) | VAF 68/198 reads (34%) | PolyPhen possibly damaging (0.884); catalogued as COSV60061106; called by muse, mutect2, varscan2
- TTN | c.16528G>A p.E5510K (on ENST00000591111; = p.E4583K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/228 reads (33%) | PolyPhen benign (0.077); catalogued as rs753975878, COSV60061188; called by muse, mutect2, varscan2
- TTN | c.15274G>A p.E5092K (on ENST00000591111; = p.E4165K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | PolyPhen benign (0.069); catalogued as COSV60061204; called by muse, mutect2, varscan2
- TUT4 | c.2113C>T p.R705W | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs369413824; called by muse, mutect2, varscan2
- VIPR1 | c.788G>A p.W263* | Nonsense Mutation (SNP) | VAF 41/100 reads (41%) | catalogued as rs780494471, COSV57297394; called by muse, mutect2, varscan2
- VPS33A | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.014); catalogued as COSV99931162; called by muse, mutect2, varscan2
- VWF | c.5096C>T p.S1699F | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM163430, COSV54620409; called by muse, mutect2, varscan2
- WDR49 | c.1762G>A p.E588K (on ENST00000308378 / NM_001366158.1; = p.E929K on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as COSV57702820; called by muse, mutect2, varscan2
- XIRP2 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.471); catalogued as COSV54687548; called by muse, mutect2, varscan2
- YEATS2 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1421301284, COSV59365379; called by muse, mutect2, varscan2
- ZBED9 | c.3625C>T p.P1209S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as COSV71729404; called by muse, mutect2, varscan2
- ZNF335 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1393077402, COSV59817811; called by muse, mutect2
- ZNF385D | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV55755827; called by muse, mutect2, varscan2
- ZNF493 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV62750064; called by muse, mutect2, varscan2
- ZNF75A | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV101556665, COSV73039620; called by muse, mutect2, varscan2
- ZNF831 | c.3323G>A p.G1108E | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64040218; called by muse, mutect2, varscan2
- ZSWIM2 | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs866692078, COSV54575450; called by mutect2, varscan2
- CBFA2T2 | c.522del p.I175Ffs*104 | Frame Shift Del (DEL) | VAF 17/50 reads (34%) | called by mutect2, pindel, varscan2
- DEFB104A | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 4/7 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.005); called by mutect2, varscan2
- GDF1 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.491); called by muse, mutect2
- GDF2 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.28); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- IGHV1-46 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- MRPS22 | c.370_411del p.R124_I137del (on ENST00000310776 / NM_001363893.1; = p.R125_I138del on NM_020191.4) | In Frame Del (DEL) | VAF 18/72 reads (25%) | called by mutect2, pindel
- MYO1A | c.2840_2843delinsCTC p.S947Tfs*11 | Frame Shift Del (DEL) | VAF 43/146 reads (29%) | called by pindel, varscan2*
- NEB | c.19205_19206del p.Y6402Ffs*2 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- RBP3 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- RCBTB1 | c.394del p.E132Kfs*2 | Frame Shift Del (DEL) | VAF 61/196 reads (31%) | called by mutect2, pindel, varscan2
- YY1 | c.861del p.E289Kfs*8 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- ABCC3 | c.252C>T p.S84= | Silent (SNP) | VAF 51/234 reads (22%) | catalogued as COSV53321729; called by muse, mutect2, varscan2
- ABCC9 | c.3144C>T p.F1048= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV53966246; called by muse, mutect2, varscan2
- AC008397.2 | c.357C>T p.S119= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV53206913; called by muse, mutect2, varscan2
- ACACA | c.6531G>A p.V2177= | Silent (SNP) | VAF 41/107 reads (38%) | called by muse, mutect2, varscan2
- ACSM3 | c.1005G>A p.Q335= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV55501433; called by muse, mutect2, varscan2
- ACSS1 | c.1575C>T p.Y525= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs750095173, COSV60220300; called by muse, mutect2, varscan2
- ACTL6B | c.594C>T p.F198= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as COSV50515011; called by muse, mutect2, varscan2
- ADAM21 | c.2058G>A p.L686= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV50793384; called by muse, mutect2, varscan2
- ADGRV1 | c.5991C>T p.I1997= | Silent (SNP) | VAF 15/22 reads (68%) | catalogued as COSV67985169; called by muse, mutect2, varscan2
- AGAP4 | c.1632C>T p.I544= | Silent (SNP) | VAF 18/64 reads (28%) | called by mutect2, varscan2
- AL669918.1 | c.2307G>A p.Q769= | Silent (SNP) | VAF 63/157 reads (40%) | catalogued as rs1045897028, COSV71270980; called by muse, mutect2, varscan2
- ALMS1 | c.9063C>T p.S3021= | Silent (SNP) | VAF 47/103 reads (46%) | catalogued as rs762273689, COSV52509909; called by muse, mutect2, varscan2
- ANO7 | c.990G>A p.Q330= (on ENST00000274979; = p.Q276= on NM_001370694.2) | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs750256912, COSV51471827; called by muse, mutect2, varscan2
- BRINP1 | c.2139G>A p.G713= | Silent (SNP) | VAF 39/111 reads (35%) | catalogued as COSV56296505, COSV56307061; called by muse, mutect2, varscan2
- C10orf71 | c.144C>T p.F48= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as COSV60507655; called by muse, mutect2, varscan2
- C2orf78 | c.2700G>A p.G900= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs1183034576, COSV68517520; called by muse, mutect2
- C9orf135 | c.660C>T p.P220= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as rs780611705, COSV65875430; called by muse, mutect2, varscan2
- CARS2 | c.687C>T p.F229= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as rs775389111, COSV57285993; called by muse, mutect2, varscan2
- CBLN2 | c.582G>A p.R194= | Silent (SNP) | VAF 47/129 reads (36%) | catalogued as COSV54050171; called by muse, mutect2, varscan2
- CCN5 | c.597G>A p.T199= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as rs537131485, COSV51937340, COSV99509361; called by muse, mutect2, varscan2
- CD163L1 | c.4197G>A p.R1399= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV58011582, COSV58025488; called by muse, mutect2
- CD300A | c.504G>A p.Q168= | Silent (SNP) | VAF 56/105 reads (53%) | catalogued as rs776573991, COSV60410120; called by muse, mutect2, varscan2
- CHI3L1 | c.600C>T p.F200= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV55138147; called by muse, mutect2, varscan2
- CHST15 | c.891C>T p.I297= | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as rs142086366; called by muse, mutect2, varscan2
- CIITA | c.447G>A p.E149= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV60857113; called by muse, mutect2
- CPNE4 | c.1515C>T p.F505= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs267599608, COSV70194298; called by muse, mutect2, varscan2
- CPT1A | c.1449C>T p.H483= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV55756135; called by muse, mutect2, varscan2
- CRACD | c.1647C>T p.L549= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV51721058; called by muse, mutect2, varscan2
- CSMD1 | c.4366C>T p.L1456= (on ENST00000520002; = p.L1455= on NM_033225.6) | Silent (SNP) | VAF 22/28 reads (79%) | catalogued as COSV100148285, COSV59323949; called by muse, mutect2, varscan2
- CYP26B1 | c.727C>T p.L243= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as COSV50011811; called by muse, mutect2, varscan2
- CYP2C9 | c.1472G>A p.*491= | Silent (SNP) | VAF 47/77 reads (61%) | catalogued as COSV53248710; called by muse, mutect2, varscan2
- CYP2F1 | c.267G>A p.V89= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as COSV58527452; called by muse, mutect2, varscan2
- CYP3A7 | c.102G>A p.K34= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV60481541; called by muse, mutect2, varscan2
- DDX23 | c.711C>T p.I237= | Silent (SNP) | VAF 41/118 reads (35%) | catalogued as COSV100339504; called by muse, mutect2, varscan2
- DDX24 | c.747C>T p.I249= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV58212473; called by muse, mutect2, varscan2
- DLG1 | c.255C>T p.S85= | Silent (SNP) | VAF 60/139 reads (43%) | catalogued as COSV58382896; called by muse, mutect2, varscan2
- DOCK3 | c.1293G>A p.G431= | Silent (SNP) | VAF 43/136 reads (32%) | catalogued as COSV56521647; called by muse, mutect2, varscan2
- DPYSL5 | c.348C>T p.C116= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV99981557; called by muse, mutect2, varscan2
- EDC3 | c.234C>T p.D78= | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as COSV59340220; called by muse, mutect2, varscan2
- EHMT1 | c.2238C>T p.A746= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV100603419; called by muse, mutect2, varscan2
- FAM71B | c.1032C>T p.A344= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as rs151185932, COSV100262158; called by muse, mutect2, varscan2
- FLII | c.3699C>T p.S1233= | Silent (SNP) | VAF 82/190 reads (43%) | catalogued as COSV57497958; called by muse, mutect2, varscan2
- FMO4 | c.48C>T p.S16= | Silent (SNP) | VAF 93/176 reads (53%) | catalogued as COSV63001150; called by muse, mutect2, varscan2
- FMR1 | c.1011C>T p.S337= | Silent (SNP) | VAF 38/50 reads (76%) | catalogued as COSV54423874; called by muse, mutect2, varscan2
- FSHB | c.198G>A p.Q66= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV54221772, COSV99569541; called by muse, mutect2
- FSHR | c.1389C>T p.I463= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as COSV58623636; called by muse, mutect2, varscan2
- FUT9 | c.969T>C p.T323= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV56146978; called by muse, mutect2, varscan2
- GALNTL5 | c.1204C>T p.L402= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as COSV67180150; called by muse, mutect2, varscan2
- GPC4 | c.1443G>A p.G481= | Silent (SNP) | VAF 55/75 reads (73%) | catalogued as COSV63697840; called by muse, mutect2, varscan2
- GRIP2 | c.594G>A p.G198= (on ENST00000619221; = p.G101= on NM_001080423.4) | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs754363222, COSV56121395; called by muse, mutect2, varscan2
- GRM7 | c.1002C>T p.I334= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV63143225; called by muse, mutect2, varscan2
- HCN4 | c.1140G>A p.T380= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs370059727; called by muse, mutect2, varscan2
- IGHV3-23 | c.108C>T p.S36= | Silent (SNP) | VAF 76/282 reads (27%) | catalogued as rs553443391; called by muse, mutect2, varscan2
- IGKV6D-21 | c.270C>T p.F90= | Silent (SNP) | VAF 59/146 reads (40%) | called by muse, mutect2, varscan2
- IL7R | c.763C>T p.L255= | Silent (SNP) | VAF 34/119 reads (29%) | catalogued as COSV57408543, COSV57415317, COSV99073412; called by muse, mutect2, varscan2
- ITGAD | c.798G>A p.L266= | Silent (SNP) | VAF 45/99 reads (45%) | catalogued as rs1217137184, COSV66757470; called by muse, mutect2, varscan2
- JCAD | c.579G>A p.R193= | Silent (SNP) | VAF 105/224 reads (47%) | catalogued as COSV64759627; called by muse, mutect2, varscan2
- JUP | c.1995C>T p.S665= | Silent (SNP) | VAF 53/143 reads (37%) | catalogued as rs782094877, COSV60277082; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- KL | c.1272G>A p.K424= | Silent (SNP) | VAF 58/150 reads (39%) | catalogued as rs1245361668, COSV66308782, COSV66309450; called by muse, mutect2, varscan2
- KMT2C | c.11658C>T p.T3886= | Silent (SNP) | VAF 123/435 reads (28%) | catalogued as rs1471458624, COSV51439456; called by muse, mutect2, varscan2
- KRTAP19-4 | c.189G>A p.L63= | Silent (SNP) | VAF 67/94 reads (71%) | catalogued as COSV61858720; called by muse, mutect2, varscan2
- LAMA1 | c.3111G>A p.A1037= | Silent (SNP) | VAF 36/116 reads (31%) | catalogued as rs200710797, COSV67533149; called by muse, mutect2, varscan2
- LGALS3BP | c.204G>A p.E68= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV53164925; called by muse, mutect2, varscan2
- LILRB2 | c.846C>T p.T282= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as COSV58745227; called by muse, mutect2, varscan2
- LRRC8C | c.1668C>T p.I556= | Silent (SNP) | VAF 30/56 reads (54%) | catalogued as COSV64997924; called by muse, mutect2, varscan2
- LRRK1 | c.1926C>T p.I642= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as COSV52611631; called by muse, mutect2, varscan2
- LY9 | c.414T>C p.F138= | Silent (SNP) | VAF 55/131 reads (42%) | catalogued as COSV54433991; called by muse, mutect2, varscan2
- MALT1 | c.1278C>T p.V426= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV61934886; called by muse, mutect2, varscan2
- MAP2 | c.4875C>T p.T1625= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV52290862, COSV52296139; called by muse, mutect2, varscan2
- MAZ | c.648G>A p.K216= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs1314566596, COSV50715071, COSV50717467; called by muse, mutect2, varscan2
- MC2R | c.186C>T p.F62= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV59618167; called by muse, mutect2, varscan2
- MIA2 | c.1845C>T p.F615= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV54483473; called by muse, mutect2, varscan2
- MUC16 | c.22590G>A p.R7530= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV67462939; called by muse, mutect2, varscan2
- MUC4 | c.13212C>T p.F4404= (on ENST00000463781 / NM_018406.7; = p.F168= on NM_004532.6) | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs373773138, COSV57804454; called by muse, mutect2, varscan2
- MYH6 | c.5103G>A p.R1701= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as rs1456703289, COSV100676148; called by muse, mutect2, varscan2
- MYH8 | c.3408G>A p.E1136= | Silent (SNP) | VAF 48/134 reads (36%) | catalogued as rs1031980265, COSV67965055; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH8 | c.72G>A p.K24= | Silent (SNP) | VAF 47/129 reads (36%) | catalogued as COSV67965061; called by muse, mutect2, varscan2
- NAALADL2 | c.1479C>T p.F493= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as rs749517499, COSV69156236; called by muse, mutect2
- NDUFB7 | c.72C>T p.T24= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV53108240; called by muse, mutect2, varscan2
- NEFM | c.951C>T p.I317= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV55332126; called by muse, mutect2, varscan2
- NLRP10 | c.666C>T p.L222= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs770023373, COSV60780240; called by muse, mutect2, varscan2
- NLRP12 | c.2976C>T p.F992= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs1230733300, COSV60747461; called by muse, mutect2, varscan2
- NLRP2 | c.2655G>A p.V885= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as rs866915434, COSV54755092; called by muse, mutect2, varscan2
- NLRP3 | c.2157G>A p.V719= | Silent (SNP) | VAF 78/180 reads (43%) | catalogued as rs201515412, COSV60224297; called by muse, mutect2, varscan2
- NOTCH1 | c.2388G>A p.A796= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs561956078, COSV53051046; ClinVar: likely benign; called by muse, mutect2, varscan2
- NPSR1 | c.544C>T p.L182= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV62200375; called by muse, mutect2, varscan2
- NTRK3 | c.2103C>T p.S701= | Silent (SNP) | VAF 53/134 reads (40%) | catalogued as COSV100712144, COSV62304253; called by muse, mutect2, varscan2
- OR10G7 | c.474G>A p.Q158= | Silent (SNP) | VAF 111/201 reads (55%) | catalogued as COSV57867076; called by muse, mutect2, varscan2
- OR10K1 | c.510C>T p.S170= | Silent (SNP) | VAF 82/278 reads (29%) | catalogued as rs769218127, COSV56871944; called by muse, mutect2, varscan2
- OR2D3 | c.927G>A p.R309= | Silent (SNP) | VAF 47/99 reads (47%) | catalogued as COSV53493044, COSV99549663; called by muse, mutect2, varscan2
- OR2L3 | c.291G>A p.G97= | Silent (SNP) | VAF 151/291 reads (52%) | catalogued as COSV63455181; called by muse, mutect2, varscan2
- OR2T29 | c.117C>T p.F39= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs756914077; called by mutect2, varscan2
- OR2T33 | c.177C>T p.F59= | Silent (SNP) | VAF 53/202 reads (26%) | catalogued as COSV58813839; called by muse, mutect2, varscan2
- OR4K5 | c.897G>A p.R299= | Silent (SNP) | VAF 30/203 reads (15%) | catalogued as rs749816085, COSV60003526; called by muse, mutect2, varscan2
- OR51A2 | c.750C>T p.I250= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as COSV66748354; called by muse, mutect2, varscan2
- OR51A4 | c.750C>T p.I250= | Silent (SNP) | VAF 21/188 reads (11%) | catalogued as COSV66749448; called by muse, mutect2, varscan2
- OR6C68 | c.117G>A p.G39= | Silent (SNP) | VAF 60/115 reads (52%) | catalogued as COSV65563290; called by muse, mutect2, varscan2
- OR7D2 | c.633C>T p.L211= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV60139811; called by muse, mutect2, varscan2
- OR8D1 | c.87C>T p.L29= | Silent (SNP) | VAF 52/82 reads (63%) | catalogued as rs1474168900, COSV63442229; called by muse, mutect2, varscan2
- OR9G4 | c.9G>A p.V3= | Silent (SNP) | VAF 36/54 reads (67%) | catalogued as COSV57248539; called by muse, mutect2, varscan2
- OXR1 | c.930G>A p.E310= (on ENST00000442977 / NM_001198532.1; = p.E309= on NM_018002.3) | Silent (SNP) | VAF 58/217 reads (27%) | catalogued as COSV56329159; called by muse, mutect2, varscan2
- PARP4 | c.1425G>A p.G475= | Silent (SNP) | VAF 24/218 reads (11%) | catalogued as COSV67965131; called by muse, mutect2, varscan2
- PASK | c.3132C>T p.P1044= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV99298401; called by muse, mutect2, varscan2
- PCDHB6 | c.642G>A p.L214= | Silent (SNP) | VAF 38/113 reads (34%) | catalogued as COSV50697807; called by muse, mutect2, varscan2
- PCNX2 | c.5979C>T p.S1993= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs1172530633, COSV50801178; called by muse, mutect2, varscan2
- PDE6A | c.2130C>T p.I710= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs750000569, COSV54927344; called by muse, mutect2, varscan2
- PGAP4 | c.312C>T p.I104= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as COSV66387658; called by muse, mutect2, varscan2
- PHYH | c.207C>T p.I69= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV53815746; called by muse, mutect2, varscan2
- PLAG1 | c.1170C>T p.S390= | Silent (SNP) | VAF 38/132 reads (29%) | catalogued as COSV57610571; called by muse, mutect2, varscan2
- PLEC | c.2370C>T p.A790= (on ENST00000322810 / NM_201380.4; = p.A680= on NM_000445.5) | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV59635937; called by muse, mutect2, varscan2
- PLIN4 | c.2952C>T p.F984= (on ENST00000301286; = p.F999= on NM_001367868.2) | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV56691166; called by muse, mutect2, varscan2
- PPARGC1B | c.2478G>A p.G826= | Silent (SNP) | VAF 39/122 reads (32%) | catalogued as COSV58529247; called by muse, mutect2, varscan2
- PRF1 | c.1212C>T p.T404= | Silent (SNP) | VAF 21/29 reads (72%) | catalogued as rs757256300, COSV64614870; called by muse, mutect2, varscan2
- PRIM1 | c.69C>T p.Y23= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs763668000, COSV57717389; called by muse, mutect2, varscan2
- PROSER3 | c.759C>T p.P253= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as COSV56553456; called by muse, mutect2, varscan2
- PSG8 | c.471C>T p.N157= | Silent (SNP) | VAF 134/310 reads (43%) | catalogued as rs140758943, COSV60611576; called by muse, mutect2, varscan2
- PSKH2 | c.435C>T p.L145= | Silent (SNP) | VAF 41/109 reads (38%) | catalogued as COSV52610490; called by muse, mutect2, varscan2
- PTCHD3 | c.468C>T p.F156= | Silent (SNP) | VAF 78/190 reads (41%) | catalogued as COSV71256799; called by muse, mutect2, varscan2
- PTH1R | c.228G>A p.G76= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100480717; called by muse, mutect2, varscan2
- PXDNL | c.3675G>A p.R1225= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV62487315; called by muse, mutect2, varscan2
- QSOX2 | c.2058C>T p.S686= | Silent (SNP) | VAF 39/108 reads (36%) | catalogued as COSV62394141; called by muse, mutect2, varscan2
- RASAL1 | c.1644G>A p.V548= | Silent (SNP) | VAF 39/111 reads (35%) | catalogued as COSV55655994; called by muse, mutect2, varscan2
- RASGRP2 | c.333G>A p.G111= | Silent (SNP) | VAF 28/41 reads (68%) | catalogued as COSV62449476; called by muse, mutect2, varscan2
- RASSF9 | c.324C>T p.P108= | Silent (SNP) | VAF 41/119 reads (34%) | catalogued as COSV63433647; called by muse, mutect2, varscan2
- REPS2 | c.1632C>T p.S544= | Silent (SNP) | VAF 59/85 reads (69%) | catalogued as COSV58182166; called by muse, mutect2, varscan2
- RFX6 | c.681C>T p.F227= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV60584267, COSV60584974; called by muse, mutect2, varscan2
- RGS22 | c.891G>A p.K297= | Silent (SNP) | VAF 45/150 reads (30%) | catalogued as COSV62661658; called by muse, mutect2, varscan2
- RHBG | c.1051C>T p.L351= | Silent (SNP) | VAF 74/159 reads (47%) | catalogued as COSV54804993; called by muse, mutect2, varscan2
- RNF17 | c.537G>A p.T179= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs267603788, COSV55039615; called by muse, mutect2, varscan2
- ROR2 | c.555C>T p.F185= | Silent (SNP) | VAF 46/111 reads (41%) | catalogued as COSV65219124; called by muse, mutect2, varscan2
- RXRA | c.894C>T p.V298= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs72554630, COSV62684253; called by muse, mutect2, varscan2
- RYR1 | c.2478G>A p.K826= | Silent (SNP) | VAF 80/176 reads (45%) | catalogued as COSV62097231; called by muse, mutect2, varscan2
- RYR2 | c.9801C>T p.A3267= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV63685605; called by muse, mutect2, varscan2
- SACS | c.13614C>T p.Y4538= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as rs927804920, COSV66539925; called by muse, mutect2, varscan2
- SDK2 | c.3927C>T p.F1309= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV66185994; called by muse, mutect2, varscan2
- SELENBP1 | c.1032C>T p.R344= | Silent (SNP) | VAF 137/274 reads (50%) | catalogued as COSV64373474; called by muse, mutect2, varscan2
- SLC26A5 | c.630C>T p.V210= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV59700116; called by muse, mutect2, varscan2
- SLC4A11 | c.2598C>T p.I866= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV66261932; called by muse, mutect2, varscan2
- SLC8A3 | c.2052C>T p.I684= (on ENST00000381269 / NM_183002.3; = p.I682= on NM_033262.4) | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV53689528; called by muse, mutect2, varscan2
- SMPD3 | c.804G>A p.R268= | Silent (SNP) | VAF 38/45 reads (84%) | catalogued as COSV54712225; called by muse, mutect2, varscan2
- SNX9 | c.120G>A p.L40= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV67584205; called by muse, mutect2, varscan2
- SPAG17 | c.1848G>A p.G616= | Silent (SNP) | VAF 46/100 reads (46%) | catalogued as COSV60458826; called by muse, mutect2, varscan2
- STAB2 | c.4314G>A p.G1438= | Silent (SNP) | VAF 43/89 reads (48%) | catalogued as rs1289984101, COSV66335138; called by muse, mutect2, varscan2
- STAT3 | c.1728C>T p.I576= | Silent (SNP) | VAF 67/170 reads (39%) | catalogued as COSV52887476; called by muse, mutect2, varscan2
- STC2 | c.816C>T p.A272= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as rs763092739, COSV54179823; called by muse, mutect2, varscan2
- STXBP2 | c.1428C>T p.T476= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs756428439, COSV55403316, COSV99656816; called by muse, mutect2, varscan2
- TEX13A | c.126C>T p.S42= | Silent (SNP) | VAF 25/36 reads (69%) | catalogued as COSV100780595; called by muse, mutect2, varscan2
- THNSL1 | c.390C>T p.S130= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV100896318, COSV64479321; called by muse, mutect2, varscan2
- TMEM178A | c.426C>T p.I142= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV56141883; called by muse, mutect2, varscan2
- TNRC18 | c.6774C>T p.D2258= | Silent (SNP) | VAF 44/79 reads (56%) | catalogued as COSV60307513; called by muse, mutect2, varscan2
- TRPM2 | c.39G>A p.Q13= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as COSV55969683; called by muse, mutect2, varscan2
- TTN | c.19533C>T p.I6511= (on ENST00000591111; = p.I5584= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as rs563320328, COSV60061177; called by muse, mutect2, varscan2
- TULP2 | c.1365G>A p.E455= | Silent (SNP) | VAF 47/101 reads (47%) | catalogued as COSV55478007, COSV55479111; called by muse, mutect2, varscan2
- UBAP2L | c.2373C>T p.L791= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV55172631, COSV55173182; called by muse, mutect2, varscan2
- VPS16 | c.486C>T p.L162= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs985736911, COSV66795072; called by muse, mutect2, varscan2
- VPS33A | c.840C>T p.L280= | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as COSV99931163; called by muse, mutect2, varscan2
- VPS9D1 | c.1158C>T p.F386= | Silent (SNP) | VAF 23/33 reads (70%) | catalogued as COSV66994410; called by muse, mutect2, varscan2
- XPNPEP3 | c.336C>T p.P112= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as COSV64026917; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1770C>T p.S590= | Silent (SNP) | VAF 32/122 reads (26%) | catalogued as COSV54295803; called by muse, mutect2, varscan2
- ZFHX4 | c.6399G>A p.R2133= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV50798091; called by muse, mutect2, varscan2
- ZFPL1 | c.384C>T p.A128= | Silent (SNP) | VAF 41/69 reads (59%) | catalogued as rs768278358, COSV51869540; called by muse, mutect2, varscan2
- ZNF479 | c.663C>T p.S221= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs1554400321, COSV58638415; called by muse, mutect2, varscan2
- ZNF594 | c.2199G>A p.E733= | Silent (SNP) | VAF 71/173 reads (41%) | catalogued as COSV68385269; called by muse, mutect2, varscan2
- ZNF629 | c.906C>T p.N302= | Silent (SNP) | VAF 59/139 reads (42%) | catalogued as COSV52697862, COSV52698572; called by muse, mutect2, varscan2
- ZNF831 | c.162C>T p.F54= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs956928821, COSV64040210; called by muse, mutect2, varscan2
- ZNF99 | c.846G>A p.K282= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV68055742, COSV68056998; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83278G>C | Intron (SNP) | VAF 113/322 reads (35%) | called by muse, mutect2, varscan2
- ATP11AUN | n.939T>A | RNA (SNP) | VAF 26/73 reads (36%) | called by muse, mutect2, varscan2
- CACNA1G | c.4422+33G>A | Intron (SNP) | VAF 48/181 reads (27%) | catalogued as COSV100660981; called by muse, mutect2, varscan2
- G6PC | c.*1G>A | 3'UTR (SNP) | VAF 41/112 reads (37%) | catalogued as COSV99520594; called by muse, mutect2, varscan2
- GCNT2 | c.925+27168C>T | Intron (SNP) | VAF 38/95 reads (40%) | catalogued as COSV100296929; called by muse, mutect2, varscan2
- KLK12 | c.*110G>A | 3'UTR (SNP) | VAF 27/82 reads (33%) | catalogued as COSV51577147; called by muse, mutect2, varscan2
- MIR1269A | n.92C>T | RNA (SNP) | VAF 22/53 reads (42%) | catalogued as rs1444997952; called by muse, mutect2, varscan2
- MIR521-1 | n.63C>T | RNA (SNP) | VAF 34/101 reads (34%) | catalogued as rs748203978; called by muse, mutect2, varscan2
- NEBL | c.164+46402C>T | Intron (SNP) | VAF 29/73 reads (40%) | catalogued as COSV65798512; called by muse, mutect2, varscan2
- PCDHGA7 | c.2424+26C>T | Intron (SNP) | VAF 11/40 reads (28%) | catalogued as COSV53933379; called by muse, mutect2, varscan2
- RPL26P30 | n.590G>A | RNA (SNP) | VAF 127/252 reads (50%) | catalogued as rs376134276; called by muse, mutect2, varscan2
- SUPT20HL2 | c.-728G>A | 5'UTR (SNP) | VAF 55/69 reads (80%) | catalogued as rs1384272061; called by muse, mutect2, varscan2
- UPB1 | c.364+255C>T | Intron (SNP) | VAF 66/151 reads (44%) | catalogued as rs573176249, COSV100387007; called by muse, mutect2, varscan2
- USP6 | c.1079-151G>A | Intron (SNP) | VAF 11/33 reads (33%) | catalogued as rs751847760, COSV100002683; called by muse, mutect2, varscan2
